MMRF case MMRF_2186 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0a8fe688-f5aa-4ef2-bbff-5a42a052f57d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.1 years (25,250 days); ISS stage: III; Days to last known disease status: 909 days (2.5 years); Days to last follow up: 909 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 41 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 4.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.33 mg/dL; Immunoglobulin G 2.44 g/L; Immunoglobulin A 68.3 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 10.3 µg/mL; Lactate Dehydrogenase 1.22 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.5 mmol/L; Albumin 27 g/L; Total Protein 9.9 g/dL; Glucose 5.17 mmol/L.
- Day 90 (ECOG 1): M Protein 0.2 g/dL; Beta 2 Microglobulin 1.5 µg/mL; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 7.4 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.08 mmol/L; Albumin 37 g/L; Total Protein 6.9 g/dL; Glucose 6.55 mmol/L.
- Day 181 (ECOG 1): Immunoglobulin G 4.81 g/L; Immunoglobulin A 2.77 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 10.2 ×10⁹/L; Absolute Neutrophil 8.52 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.13 mmol/L; Albumin 36 g/L; Total Protein 5.6 g/dL; Glucose 5.89 mmol/L.
- Day 279 (ECOG 1): Immunoglobulin G 7.06 g/L; Immunoglobulin A 2.5 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.13 mmol/L; Albumin 26 g/L; Total Protein 5 g/dL; Glucose 5.01 mmol/L.
- Day 349 (ECOG 1): Immunoglobulin G 10.3 g/L; Immunoglobulin A 4.02 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 325 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 1.98 mmol/L; Albumin 26 g/L; Total Protein 5.3 g/dL; Glucose 5.72 mmol/L.
- Day 447 (ECOG 1): Immunoglobulin G 10.1 g/L; Immunoglobulin A 3.85 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 3.9 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 16.6 ×10⁹/L; Absolute Neutrophil 14.4 ×10⁹/L; Platelets 306 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 1.95 mmol/L; Albumin 24 g/L; Total Protein 4.9 g/dL; Glucose 6.6 mmol/L.
- Day 531 (ECOG 0): Hemoglobin 6.39 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 389 ×10⁹/L.
- Day 615 (ECOG 1): Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 300 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2 mmol/L; Albumin 31 g/L; Total Protein 6.2 g/dL; Glucose 6.33 mmol/L.
- Day 748: Immunoglobulin G 11.4 g/L; Immunoglobulin A 5.49 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 4.2 µg/mL; Hemoglobin 7.32 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.8 g/dL; Glucose 5.5 mmol/L.
- Day 820: Beta 2 Microglobulin 3.6 µg/mL; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 5.89 mmol/L.
- Day 909 (ECOG 1): Immunoglobulin G 10.4 g/L; Immunoglobulin A 5.07 g/L; Beta 2 Microglobulin 3.3 µg/mL; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.13 mmol/L; Albumin 34 g/L; Total Protein 6.6 g/dL; Glucose 5.45 mmol/L.

Other clinical attributes
- Day -6: Weight: 140 kg; Height: 180 cm.

Family history
- Relative with cancer history: yes; Relationship type: Paternal Grandmother; Relationship primary diagnosis: Leukemia; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2186_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2186_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
